Somatic mutation profile of tumor specimen 0DQ8XT from CCDI case PBCENF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.8 years (2,844 days).
Specimen 0DQ8XT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1701c8e2-4de9-4d37-bc9e-76ddffcbf172.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ8YD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/333db1cd-9835-4cca-8034-573d6deb970b

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, 5'UTR 1, Splice Site 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 230/724 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, varscan2
- DHX9 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 66/2100 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV62362521; called by muse, mutect2
- RHOBTB1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 467/1340 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1157759221; called by muse, mutect2, varscan2
- SERPINE1 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 54/824 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99776749; called by muse, mutect2
- ADAM21 | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 60/1486 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- NOX3 | c.1308+1G>T p.X436_splice | Splice Site (SNP) | VAF 555/1600 reads (35%) | called by muse, mutect2, varscan2
- POU1F1 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 458/1564 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); called by mutect2, varscan2
- MANSC4 | c.978C>T p.S326= | Silent (SNP) | VAF 402/924 reads (44%) | catalogued as COSV67149061; called by muse, mutect2, varscan2
- CBLB | c.2570-62T>A | Intron (SNP) | VAF 14/403 reads (3%) | called by muse, mutect2
- NISCH | c.766-68G>A | Intron (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- PRR29 | c.*1830A>G | 3'UTR (SNP) | VAF 73/316 reads (23%) | called by muse, mutect2, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 36/1216 reads (3%) | called by muse, mutect2
- SMAD5 | c.-51C>G | 5'UTR (SNP) | VAF 117/302 reads (39%) | called by muse, mutect2, varscan2
